Somatic mutation profile of tumor specimen C3N-01079-01 (aliquot CPT0211120007) from CPTAC case C3N-01079, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; Tumor grade: G1.
Specimen C3N-01079-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11fc2974-c5ad-4c3b-ace4-d8e66d1ea8c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01079-71 (Blood Derived Normal), aliquot CPT0211240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a1a63fa-4b62-44e3-b272-9d2761f63fa5

The open-access MAF lists 78 somatic variants for this specimen: 47 protein-altering or splice-affecting, 24 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 24, Intron 3, 5'Flank 2, 5'UTR 2, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 56/144 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/370 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 73/122 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5664C>A p.F1888L | Missense Mutation (SNP) | VAF 108/206 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63869154, COSV63870934; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 205/391 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14548G>A p.A4850T | Missense Mutation (SNP) | VAF 129/367 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs746265472, COSV68946323; called by muse, mutect2, varscan2
- ALDH1L1 | c.2326G>A p.G776R | Missense Mutation (SNP) | VAF 110/218 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375361827, COSV99856391; called by muse, mutect2, varscan2
- ARAP1 | c.1486C>T p.R496C (on ENST00000393609 / NM_001040118.2; = p.R251C on NM_015242.4) | Missense Mutation (SNP) | VAF 116/395 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs776130856, COSV61989262; called by muse, mutect2, varscan2
- C19orf44 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs749553167; called by muse, mutect2
- DLG5 | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64946873, COSV64947137; called by muse, mutect2, varscan2
- DNAH17 | c.4018G>A p.V1340M | Missense Mutation (SNP) | VAF 218/465 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs371041605; called by muse, mutect2, varscan2
- DUXB | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 87/374 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as rs1414847776; called by muse, mutect2, varscan2
- ERICH5 | c.742A>G p.T248A | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.13); catalogued as rs1283787434; called by muse, mutect2, varscan2
- GGT7 | c.555C>T p.G185= | Splice Region (SNP) | VAF 214/643 reads (33%) | catalogued as COSV60539636; called by muse, mutect2, varscan2
- GPR20 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs556120969; called by muse, mutect2, varscan2
- GRID2 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs200490934, COSV56199169; called by muse, mutect2, varscan2
- IL9R | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 133/548 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as rs764877822; called by muse, mutect2, varscan2
- IRX1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 89/277 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs755172641, COSV57360839; called by muse, mutect2, varscan2
- KBTBD2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs142849428; called by muse, mutect2, varscan2
- MCTP2 | c.1652A>T p.N551I | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV59144104; called by muse, mutect2
- MYO9B | c.5164C>T p.H1722Y | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.999); catalogued as rs759327014; called by muse, mutect2, varscan2
- NF1 | c.4351A>T p.N1451Y (on ENST00000358273 / NM_001042492.3; = p.N1430Y on NM_000267.3) | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM113590, CM145716; called by muse, mutect2, varscan2
- NISCH | c.4169A>G p.Y1390C | Missense Mutation (SNP) | VAF 128/314 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV100402360; called by muse, mutect2, varscan2
- OR5P2 | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as rs995089649; called by muse, mutect2, varscan2
- OR9G4 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs139616824, COSV57248756; called by muse, mutect2, varscan2
- PCNX3 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs1174802363; called by muse, mutect2, varscan2
- RNASE4 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 123/328 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs374269522, COSV59011986; called by muse, mutect2, varscan2
- SLC35F4 | c.752G>T p.R251I (on ENST00000339762 / NM_001352015.2; = p.R215I on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1312100990, COSV60265648; called by muse, mutect2, varscan2
- SNPH | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs183333437; called by muse, mutect2, varscan2
- SPOP | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 83/153 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61655698, COSV61656254; called by muse, mutect2, varscan2
- SYT10 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs143923961; called by muse, mutect2
- TPO | c.2515G>A p.V839I | Missense Mutation (SNP) | VAF 103/515 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs146351101, CM024371; called by muse, mutect2, varscan2
- USP29 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.894); catalogued as rs747408433, COSV54146220; called by muse, mutect2, varscan2
- BSN | c.7382_7396del p.Q2461_Q2465del | In Frame Del (DEL) | VAF 40/130 reads (31%) | called by mutect2, varscan2
- CALR | c.1012T>A p.Y338N | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CPS1 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 123/308 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- DRD2 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 124/401 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FNTA | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- GMDS | c.159T>G p.I53M | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- OTULINL | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PCBP1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 196/500 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRKAA1 | c.518A>T p.N173I | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PTCHD4 | c.1317C>A p.N439K | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC35G2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLCO1B1 | c.1015G>T p.V339F | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TGFBR2 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- UCP3 | c.119_120del p.R40Pfs*32 | Frame Shift Del (DEL) | VAF 84/335 reads (25%) | called by mutect2, pindel, varscan2
- CFAP65 | c.2730C>T p.P910= | Silent (SNP) | VAF 140/298 reads (47%) | called by muse, mutect2, varscan2
- COL18A1 | c.4296C>T p.P1432= (on ENST00000359759 / NM_130444.3; = p.P1197= on NM_030582.4) | Silent (SNP) | VAF 86/449 reads (19%) | called by muse, mutect2, varscan2
- CRMP1 | c.1368C>T p.D456= | Silent (SNP) | VAF 63/251 reads (25%) | catalogued as rs146365732; called by muse, mutect2, varscan2
- EEPD1 | c.1575C>T p.G525= | Silent (SNP) | VAF 116/326 reads (36%) | catalogued as rs1349063736; called by muse, mutect2, varscan2
- EPN1 | c.1398C>A p.P466= (on ENST00000270460 / NM_001321263.1; = p.P440= on NM_013333.3) | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as rs763683773, COSV50036066; called by muse, mutect2, varscan2
- ERVFRD-1 | c.1035G>A p.L345= | Silent (SNP) | VAF 45/196 reads (23%) | called by muse, mutect2, varscan2
- FLNC | c.4035C>T p.T1345= | Silent (SNP) | VAF 224/558 reads (40%) | catalogued as rs538733304, COSV57956550; ClinVar: likely benign; called by muse, mutect2, varscan2
- HMCN2 | c.13701C>T p.N4567= | Silent (SNP) | VAF 210/422 reads (50%) | catalogued as rs1396620930; called by muse, mutect2, varscan2
- IGHG2 | c.9C>A p.T3= | Silent (SNP) | VAF 186/474 reads (39%) | called by muse, mutect2, varscan2
- KIF1A | c.3639C>T p.I1213= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as rs201423643; called by muse, mutect2, varscan2
- MUC16 | c.34770G>A p.G11590= | Silent (SNP) | VAF 65/306 reads (21%) | called by muse, mutect2
- NLRP3 | c.2685G>A p.T895= | Silent (SNP) | VAF 316/656 reads (48%) | catalogued as rs778287953, COSV60223984; called by muse, mutect2, varscan2
- OBSL1 | c.4908C>T p.H1636= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as rs754529663, COSV99522702; called by muse, mutect2, varscan2
- PIK3CG | c.2385G>A p.A795= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as rs370008815; called by muse, mutect2, varscan2
- PLEKHA7 | c.2002C>T p.L668= | Silent (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- PTPRD | c.1026G>A p.T342= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as rs753352248, COSV61975963; called by muse, mutect2, varscan2
- PXDN | c.2919C>T p.A973= | Silent (SNP) | VAF 59/286 reads (21%) | catalogued as rs780425357, COSV53246028; called by muse, mutect2, varscan2
- RTN2 | c.501G>A p.P167= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs777614999, COSV55594979; called by muse, mutect2, varscan2
- SLCO5A1 | c.411G>T p.L137= | Silent (SNP) | VAF 31/382 reads (8%) | catalogued as COSV52667063; called by muse, mutect2
- SSTR4 | c.459C>T p.R153= | Silent (SNP) | VAF 66/173 reads (38%) | catalogued as rs373043966, COSV54799414; called by muse, mutect2, varscan2
- TNKS | c.1182T>C p.D394= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs1487468324; called by muse, mutect2, varscan2
- TNS2 | c.2844T>C p.P948= (on ENST00000314250 / NM_170754.4; = p.P958= on NM_015319.2) | Silent (SNP) | VAF 64/108 reads (59%) | catalogued as rs763094056; called by muse, mutect2, varscan2
- TRIM64C | c.816A>G p.S272= | Silent (SNP) | VAF 84/293 reads (29%) | catalogued as rs1423018228; called by muse, mutect2, varscan2
- ZNF536 | c.3279C>T p.S1093= | Silent (SNP) | VAF 108/396 reads (27%) | catalogued as rs147863190; called by muse, mutect2, varscan2
- AC244517.10 | c.36-10066G>A | Intron (SNP) | VAF 41/132 reads (31%) | catalogued as rs1414016131; called by muse, mutect2, varscan2
- MUCL3 | c.947-762C>A | Intron (SNP) | VAF 49/233 reads (21%) | called by muse, mutect2, varscan2
- NDP | c.-13T>C | 5'UTR (SNP) | VAF 92/327 reads (28%) | called by muse, mutect2, varscan2
- NPHS1 | c.-51C>T | 5'UTR (SNP) | VAF 94/242 reads (39%) | catalogued as rs373805932; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159651 G>A | 5'Flank (SNP) | VAF 56/149 reads (38%) | catalogued as rs1438455614; called by muse, mutect2, varscan2
- S1PR3 | chr9:88991196 G>C | 5'Flank (SNP) | VAF 137/306 reads (45%) | catalogued as rs774721827; called by muse, mutect2, varscan2
- SSR4 | c.262-40G>A | Intron (SNP) | VAF 22/270 reads (8%) | catalogued as rs1557072959; called by muse, mutect2
